Surgical pathology report (de-identified scan), TCGA case TCGA-IB-AAUM, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Alberta Health Services, specimen TCGA-IB-AAUM-01A (Primary Tumor).

[page 1 of 3]
CONFIDENTIAL

SURGICAL PATHOLOGY REPORT

Time Collected		Time Received	
Time Reported		Time Transmitted	
Order Number		Ordering Provider	
Status	Final	Relevant Information	
		Location	

Report Patient Name:
Demographics (for verification purposes) Date of Birth:
Sex: M

SURGICAL PATHOLOGY REPORT

*****Surgical Pathology Report*****

Accession Number
Collected Date/Time
Received Date/Time
Pathologist
Specimen Description
A: Paraportal lymph node at
B: Gallbladder at
C: Whipple at
D: Distal bile duct margin at
E: Pancreatic bile duct margin at
F: Retroperitoneal margin at
Clinical Information
Pancreatic cancer, tumor
Infectious patient: No
Immunocompromised: Not given
History of neoplasm: Not given

(Pager:

ICD-O-3
Adenocarcinoma duet NOS 8500/3
Carcinoma, mixed mucinous &
infiltrating duet 8523/3
Site: pancreas head C25.0
Pancreas NOS C25.9

Diagnosis

- A: Paraportal Lymph Node:
- Fibrofatty tissue only
B: Gallbladder:
- Chronic cholecystitis
C: Whipple:
- Ductal carcinoma, mucinous variant
- Pancreatic intraepithelial neoplasia
- One peripancreatic lymph node with metastatic carcinoma present by the bile duct margin (positive margin).
D: Distal Bile Duct Margin:
- Negative for malignancy
E: Pancreatic Bile Duct Margin:
- Negative for malignancy
F: Retroperitoneal Margin:
- Negative for malignancy

Reported by:
Electronically signed by:
Verified:

Synoptic Report
HISTOLOGIC TYPE:
Ductal adenocarcinoma
HISTOLOGIC GRADE:
G3: Poorly differentiated
MICROSCOPIC TUMOR EXTENSION:
Tumor invades duodenal wall

[page 2 of 3]
MARGINS:

Margin(s) involved by invasive carcinoma

Common bile duct margin

TREATMENT EFFECT (applicable to carcinomas treated with neoadjuvant therapy):

No prior treatment

LYMPH-VASCULAR INVASION:

Not identified

PERINEURAL INVASION:

Present

PRIMARY TUMOR (pT):

pT2: Tumor limited to the pancreas, more than 2 cm in greatest dimension

REGIONAL LYMPH NODES (pN):

pN1: Regional lymph node metastasis

Number examined: 1

ADDITIONAL PATHOLOGIC FINDINGS:

Pancreatic intraepithelial neoplasia (highest grade: PanIN low grade)

Gross Description

Received are specimen containers A to F. All submissions and specimen containers are labelled with the patient's name, . The cassettes and identifiers are labelled with the Surgical Number

A: The specimen is received fresh and is subsequently placed into formalin and designated as A parportal lymph node and contains a yellow hemorrhagic irregular portion of adipose tissue measuring 3.8 cm in maximum dimension. Specimen is serially sectioned. No possible lymph nodes are identified on the cut surface.

A1/2. serial sectioned specimen in toto

B: The specimen is received fresh and is subsequently placed into formalin and designated as B gallbladder and contains a non intact gallbladder measuring 7.5 x 3.2 x 1.5 cm. Cystic duct resection margin is identified and appears patent. Cystic duct lymph node is not grossly identified. The serosal surface reveals slightly congested smooth glistening appearance. The advential surface is non intact and reveals green stained roughened appearance. Mucosal surface of the gallbladder reveals dark brown slightly velvety appearance. No stones are identified inside the lumen or in the container. The wall thickness of the gallbladder ranges from 0.1 to 0.5 cm. A thickened area of the wall is identified at the neck and body.

B1. sections from neck, body, and fundus, cystic duct resection margin

B2. further sections from the thickened area of the wall

C: The specimen is received fresh and is subsequently placed into formalin and designated as C Whipple and contains a portion of distal stomach with attached portion of duodenum and attached portion of pancreas. The portion of distal stomach measures 5 cm in length and 6 cm circumference at the proximal resection margin. The attached adipose tissue at the proximal end measures 2.3 cm in maximum depth. The mucosal surface of the distal end of the stomach reveals multiple tan mucosal nodules. These nodules range from less than 0.1 to 0.4 cm. These nodules are spreading circumferentially in an area measuring 6 cm transversely by 1.8 cm longitudinally. This nodular area comes to within 2.3 cm of the closest proximal resection margin and 4 cm away from the ampulla of Vater. Cut surface of the nodular area reveals light tan homogeneous appearance contained in the wall of the stomach. This homogeneous area comes to within 0.2 cm of the serosal surface of the stomach. The remaining mucosal surface of the stomach reveals grossly unremarkable. The attached portion of duodenum measures 19.5 cm in length and 10 cm circumference at the distal resection margin. A light tan firm polypoid lesion is identified on the mucosal surface of the proximal duodenum measuring 1.2 cm transversely by 1.1 cm longitudinally. This area comes to within approximately 1.5 cm of the distal end of the stomach, 16.5 cm of the distal resection margin of the duodenum, 5.8 cm of the proximal resection margin of the stomach. This area also identified 1.4 cm proximal to the ampulla of Vater. The mucosal surface surrounding the ampulla of Vater reveals multiple mucosal polyps ranging from 0.3 to 0.5 cm. The mucosal surface between the polypoid lesion on the proximal end of the duodenum and ampulla of Vater reveals slightly congested firm appearance. This area measures 2.1 x 2 cm. Cut surface of the firm polypoid area on the proximal mucosa surface of the duodenum reveals light tan homogeneous appearance grossly extending to the bowel wall and grossly coming to within 0.2 cm of the pancreatic tissue. The homogenous area measures 0.5 cm in maximum depth. A tan sessile polyp is identified distal to the ampulla of Vater and measures 0.6 cm in maximum dimension. This polyp is identified 3 cm away from the slightly congested firm area on the mucosal surface surrounding the ampulla of Vater. The remaining mucosal surface of the duodenum reveal tan to congested otherwise grossly unremarkable appearance. The serosal surface of the duodenum reveals tan smooth appearance. The attached pancreas measures 5.7 x 4 x 1.5 cm. The pancreatic neck margin is marked with orange dye and the distal pancreatic margin is marked with blue dye. The vessel bed is marked with green dye. The bile duct resection margin is identified and measures 0.5 cm at the distal end. The cut surface of the pancreas reveals light tan ill defined slightly firm area occupying more than 50% of the cut surface of the pancreas and

[page 3 of 3]
approximately measuring 3 x 1.5 x 1 cm. This area grossly comes to within less than 0.1 cm of the orange inked pancreatic margin and grossly extending to the vessel bed and the distal pancreatic margin.

The inner wall of the bile duct reveals tan grossly unremarkable appearance, however, the lumen circumference of the bile duct ranges from 0.9 to 2.4 cm. The most dilated area of the lumen is identified at the distal end and this area measures 3 cm in length. Photos are taken. Sections are submitted as follows:

- C1. distal bile duct resection margin
- C2/3. longitudinal sections from the proximal end of the stomach including polypoid nodular area on the mucosal surface (distal margin margin with blue dye)
- C4. remaining proximal resection margin of the stomach shaved and in toto
- C5-7. further sections from the nodular area on the mucosal surface of the distal stomach
- C8/9. contiguous sections bisected from proximal to distal including nodular area on the distal stomach and light tan firm polypoid lesion on proximal duodenum
- C10-14. sections from light tan firm polypoid lesion in toto, C10 including portion of bile duct and C13/14 including pancreatic tissue and pancreatic duct
- C15-17. polypoid area of the ampulla of Vater in toto including adjacent pancreatic tissue
- C18/19. further sections from the bile duct, longitudinal sections, also including pancreatic tissue
- C20. slightly firm congested area surrounding the ampulla of Vater in toto
- C21. tan sessile polyp on the duodenal mucosa in toto
- C22. random sections from the remaining duodenal mucosa
- C23-25. distal duodenal resection margin shaved
- C26-29. sections from the pancreatic tissue including pancreatic neck margin, vessel bed, and pancreatic distal margin

D: The specimen consists of soft tissue fragment 0.8 x 0.3 x 0.2 cm, submitted in toto for frozen section.

Specimen is received fresh. The container is designated D distal bile duct margin.

E: The specimen consists of soft tissue fragment 1.2 x 0.8 x 0.2 cm, submitted in toto for frozen section.

The specimen is received fresh and designated E pancreatic duct margin.

F: The specimen consists of soft tissue fragment 0.9 x 0.7 x 0.2 cm, submitted in toto for frozen section.

Specimen is received fresh. The container is designated F retroperitoneal margin.

Frozen Section Diagnosis

- D: Distal Bile Duct Margin:
- Negative for malignancy
- E: Pancreatic Duct Margin:
- Negative for malignancy
- F: Retroperitoneal Margin:
- Negative for malignancy

Reported by:

Accession Number
Encounter Number
Patient Location

Source: NCI Genomic Data Commons file 83225286-6479-45f6-a9c7-1372fe6906c7 (TCGA-IB-AAUM.D1BB2C1B-DE74-4597-AA61-35CB19E069C6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).